Surgical pathology report (de-identified scan), TCGA case TCGA-24-2029, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2029-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

[REDACTED]

DIAGNOSIS-----

[REDACTED] TCGA-24-2029

SOFT TISSUE, "PELVIC MASS", BIOPSY:

- MODERATELY TO POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA, FIGO GRADE II (SEE COMMENT)

"TUMOR TISSUE", SITE NOT SPECIFIED, BIOPSY:

- MODERATELY TO POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA, FIGO GRADE II

OVARIES, RIGHT AND LEFT, SALPINGO-OOPHORECTOMY:

- MODERATELY TO POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA, FIGO GRADE II (SEE COMMENT)

FALLOPIAN TUBES, RIGHT AND LEFT, SALPINGO-OOPHORECTOMY:

- SEROSAL INVOLVEMENT BY PAPILLARY SEROUS ADENOCARCINOMA

UTERUS, CERVIX, HYSTERECTOMY:

- INTRALYMPHATIC FOCI OF METASTATIC SEROUS ADENOCARCINOMA
- ENDOCERVICAL POLYPS

UTERUS, MYOMETRIUM, HYSTERECTOMY:

- SEROSAL INVOLVEMENT BY PAPILLARY SEROUS ADENOCARCINOMA
- INTRAMURAL LEIOMYOMATA

UTERUS, ENDOMETRIUM, HYSTERECTOMY:

- ENDOMETRIAL POLYP (1.0 CM)
- SUBMUCOSAL LEIOMYOMA (1.5 CM)
- ATROPHIC ENDOMETRIUM
- [REDACTED]
-

[page 2 of 6]
[REDACTED]

Name: [REDACTED]

SPECIMEN(S) SUBMITTED

Part 1: FS1-SOFT TISSUE, PELVIS, BIOPSY
Part 2: X1-SOFT TISSUE, PELVIS, BIOPSY
Part 3: LEFT ADNEXAL MASS
Part 4: RIGHT ADNEXAL
Part 5: UTERUS, CERVIX
Part 6: TUMOR TISSUE

HISTORY

The patient is a [REDACTED] with clinical history of colon [REDACTED] post left colectomy in [REDACTED], history of breast cancer, status post left mastectomy in [REDACTED]. [REDACTED] now presents with pelvic mass and increasing abdominal distention. Operative procedure and findings: Sigmoid/mesenteric tumor mass adherent to the abdominal wall. Gross tumor noted throughout the pelvis/abdomen with peritoneal studding. Ovaries enlarged with tumor. Clinical diagnosis: Left adnexal mass.

FROZEN

FS1: Soft tissue, pelvis, biopsy - "Papillary carcinoma with psammoma bodies, favor Mullerian tract origin."
[REDACTED]

GROSS

The specimens are received in six containers of formalin, each labelled with the patient's name. The first container is labeled "FS1," and consists of a flat irregular fragment of firm yellow-white tissue that represents the remnant of the frozen section, and measures 1.8 x 1.3 x 0.3 cm. [REDACTED]

The second container is labeled "X1-pelvic mass," and consists of an irregular, rubbery to firm soft tissue fragment that has been previously sectioned and sampled, that measures 3.0 x 1.5 x 1.5 upon reconstruction. The cut surfaces demonstrate a variably

[page 3 of 6]
[REDACTED] [REDACTED] [REDACTED]

[REDACTED]

Surg. Path. No.:

Name:

GROSS (continued)

yellow to white, firm granular cut surface. Further sectioned and labeled X1 and X2. [REDACTED]

The third container is labeled "left adnexal mass," and consists of a segment of fallopian tube that includes the fimbriated end, and measures 5.0 cm in length and up to 1.0 cm in diameter. The serosa is hemorrhagic and shaggy with numerous fibrous adhesions. Attached to the mesovarium is a firm, irregular mass that may represent the ovary, and measures 3.8 x 3.0 x 2.0 cm. The surface of this nodule is focally granular and hemorrhagic with numerous fibrous adhesions. Serial sectioning through the possible ovarian mass demonstrates scattered thin walled, smooth lined cysts ranging from 0.3 up to 1.0 cm in greatest dimension and adjacent scattered corpora albicantia. Focal tan-white nodularities ranging from 0.2 up to 0.5 cm in greatest dimension are noted in the cortex. Blocks submitted, A1 through A6 ovary and attached mesovarium; A7 fallopian tube. [REDACTED]

The fourth container is labeled "right adnexa," and consists of a firm, multicystic mass that likely represents the ovary, and measures 4.8 x 3.0 x 2.5 cm. The serosal surface is predominantly smooth, shows numerous fibrous adhesions and scattered firm nodularities adherent to the surface. Serial sectioning of the ovary demonstrates numerous thin walled, smooth lined cysts filled with clear fluid ranging in size from 0.1 up to 1.3 cm in greatest dimension. The remaining ovarian parenchyma shows scattered corpora albicantia. The ovarian surface shows several irregular, tan-grey excrescences on the serosa. A separate segment of what appears to be fallopian tube that includes the fimbriated end is also present in the container, and measures 5.0 cm in length and up to 0.9 cm in diameter, and is covered by a focally hemorrhagic serosa with scattered fibrous adhesions. Blocks submitted, B1 through B6 right ovary; B7 right fallopian tube. [REDACTED]

The fifth container is labeled "uterus and cervix (two parts)", and consists of two separate fragments that weigh in aggregate 52 grams. The larger fragment represents the uterine corpus, and measures 4.5 x 4.0 x 3.5 cm. The serosa overlying this fragment is focally roughened, thickened, and hemorrhagic with stringy

[page 4 of 6]
Name:

Surg. Path. No.:

GROSS (continued)

fibrous adhesions. The smaller fragment represents the cervix, and measures 3.8 cm in length and up to 2.8 cm in diameter. The cervix measures 2.8 x 2.3 cm, and shows a pinpoint os that measures 0.2 cm in diameter. The ectocervical mucosa is smooth, but shows petechial hemorrhages. The cervix is opened to reveal a small endocervical polyp measuring 0.5 x 0.5 x 0.3 cm. Radial sections to the cervix appear otherwise grossly unremarkable. The larger fragment representing the uterine corpus is bivalved, demonstrating a roughly triangular endometrial cavity that measures 3.0 x 2.0 cm, and is lined by a focally hemorrhagic light tan endometrium that measures up to 0.3 cm in thickness. Two polypoid lesions arise from one aspect of the endometrial cavity, one which appears to be soft and mucosal based measuring 1.0 x 0.5 x 0.3 cm. The larger polypoid mass is rubbery and tan-white with focal surface calcification, and measures 1.5 x 1.0 x 1.0 cm. Cut surface of this larger polypoid mass shows a whorled, tan-white appearance, grossly consistent with a submucosal leiomyoma. Further sectioning through the remainder of the endomyometrium shows a uniformly trabeculated pink-tan myometrium that measures up to 1.5 cm in thickness. Blocks submitted, C1 and C2 cervix; C3 through C5 endomyometrium; C6 additional uterine serosa.

The sixth container is labeled "tumor tissue," and consists of a single rubbery to firm irregular fragment of fibrofatty tissue that measures 3.5 x 2.0 x 1.0 cm. The fragment is partially covered by a focally hemorrhagic membrane. Cross sectioning demonstrates fibrofatty tissue largely replaced by fibrous tumor with focal areas of hemorrhage. Labeled D1 and D2. Jar 0.

COMMENT

The "pelvic mass" and "tumor tissue" biopsies both show nodules of moderately to poorly differentiated papillary serous adenocarcinoma with associated psammoma bodies infiltrating within a fibroblastic stroma. Lymphatic invasion is identified. The tumor shows a predominant papillary architecture with scattered solid proliferations, and is characterized by large polygonal cells with abundant eosinophilic cytoplasm and enlarged pleomorphic nuclei with prominent nucleoli. Scattered markedly

[page 5 of 6]
Name:

Surg. Path. No.:

COMMENT (continued)

enlarged nuclei and multinucleated forms are present, and atypical mitoses are easily identified. The largest nodule of tumor measures 3.5 cm in greatest dimension.

~~Both the right and left ovaries show multiple nodules of papillary serous adenocarcinoma that predominantly involves the ovarian surfaces. The largest nodule in the ovary measures 0.7 cm in greatest dimension. The ovaries otherwise contain numerous benign cysts lined by serous or flattened cuboidal epithelium. Serosal involvement of both fallopian tubes are present.~~

The hysterectomy specimen shows patchy serosal involvement by serous papillary carcinoma and foci of intralymphatic tumor in the cervix. Benign endocervical polyps, a 1 cm endometrial polyp, and a 1.5 cm submucosal leiomyoma and multiple intramural leiomyomata are also noted.

In summary, although both ovaries are involved by serous papillary adenocarcinoma, the ovaries are not markedly enlarged, and show predominantly surface involvement. The bulk of the tumor appears to involve the pelvis and peritoneum, and raises the possibility of a primary peritoneal origin of the tumor with metastatic involvement of the ovaries. There is no evidence of metastatic colonic or breast carcinoma.

{End of Report}

Source: NCI Genomic Data Commons file 9fa7d29d-c24b-421c-9c6f-cd396183c92f (TCGA-24-2029.5F35022F-E127-4EAA-99DB-C4CA8A75F610.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).